Surgical pathology report (de-identified scan), TCGA case TCGA-D3-A51H, project TCGA-SKCM (Skin Cutaneous Melanoma), tissue source site MD Anderson, specimen TCGA-D3-A51H-06A (Metastatic).

[page 1 of 2]
DIAGNOSIS

(A) RIGHT AXILLARY CONTENTS, LEVEL 1, 2 AND 3:

MELANOMA, METASTATIC TO TWENTY-THREE OF TWENTY-THREE LYMPH NODES (23/23).

Largest tumor deposit size: 60.0 x 40.0 mm.

Location: SUBCAPSULAR AND INTRAPARENCHYMAL

Extracapsular extension: PRESENT

There is extensive regression in some of the nodules

Ulcerated skin and subcutis with abscess and granulation tissue.

(B) AXILLA, SKIN ELLIPSE:

Skin and subcutis with healing surgical wound.

Melanoma not identified. Margins have been evaluated.

(C) AXILLA, SKIN UNSPECIFIED PROCEDURE:

MELANOMA, METASTATIC TO FOUR OF FIVE LYMPH NODES (4/5).

Largest tumor deposit size: 5.0 x 4.0 mm.

Location: SUBCAPSULAR AND INTRAPARENCHYMAL

Extracapsular extension: NOT IDENTIFIED.

Skin with scar.

ICD-0-3

Melanoma, NOS 8720/3

Site: lymph nodes, subcapsular c77.3

hw
11/6/12

GROSS DESCRIPTION

(A) RIGHT AXILLARY CONTENTS, LEVEL 1, 2 AND 3 WITH OVERLYING INVOLVED ULCERATED SKIN AND PORTION OF PECTORALIS MAJOR AND LATISSIMUS DORSI MUSCLE - The specimen measures 16.5 x 9.0 x 7.0 cm soft tissue covered by an ellipse of skin (11.0 x 7.2 cm). The skin is remarkable for hyperpigmented ulcer (3.2 x 2.5 cm) located 1.1 cm from the closest skin margin. The specimen is dissected to reveal twenty three lymph nodes ranging from 1.0 to 5.5 cm with one large matted lymph node (6.0 x 4.0 x 4.0 cm). Representative sections submitted in twenty-eight cassettes as follows.

SECTION CODE: A1-A4, four ends of the skin ellipse, the margin inked blue and submitted ink side up; A5, A6, representative sections from the hyperpigmented area of the skin with ulceration; A7, four lymph nodes; A8-A18, one lymph node bisected in each cassette; A19-A26, representative sections from the large lymph nodes (all lymph nodes are grossly positive, one lymph node in each cassette); A27, A28, four representative sections from the matted lymph node.

Representative sections from the lymph nodes are submitted for tissue bank.

(B) SUPERIOR ASPECT AXILLARY SKIN - A triangular shave of skin measuring 6.7 x 3.0 cm and excised to a depth of 0.4 cm. The skin is grossly unremarkable. The peripheral margin and the deep margin is inked blue. Representative sections are submitted in three cassettes as follows.

SECTION CODE: B1, B2, true side margin, shaved and submitted entirely, ink side up; B3, two representative sections from the skin with deep margin; and side not true margin.

(C) ADDITIONAL INFERIOR AXILLARY SKIN AND SUBCUTANEOUS TISSUE - A triangular shape of skin (13.0 x 4.5 cm and excised to a depth of 2.0 cm). Also received with the specimen is a piece of adipose tissue (3.0 x 2.0 x 1.0 cm). The adipose tissue is dissected to reveal four lymph nodes ranging from 0.5 cm to 1.6 cm. The lymph nodes are submitted entirely in three cassettes.

INK CODE: The triangular shape of skin is inked as follows: true and the deep margin - blue.

SECTION CODE: C1, two lymph nodes; C2, C3, one lymph node bisected in each cassette; representative sections from the triangular shape are submitted in cassette C4-C9 as follows: C4, tip, ink side up; C5-C8, true margin, shaved, ink side up, true margin shaved ink side up; C9, two representative sections of the deep margin.

CLINICAL HISTORY

Melanoma.

SNOMED CODES

M-87206, M-78060

M-78060

M-87206, M-78060

Some tests reported here may have been developed and performance characteristics determined by specifically cleared or approved by the U.S. Food and Drug Administration.

These tests have not been

[page 2 of 2]
Entire report and diagnosis completed by:

-----END OF REPORT-----

11/6/12

Source: NCI Genomic Data Commons file fc35d8b5-cc81-4479-a76b-9501a6628701 (TCGA-D3-A51H.7A6F8B74-E5BC-4447-90CF-AE24F44FBFED.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).